Gene-level copy-number profile of tumor specimen TCGA-32-4208-01A from TCGA case TCGA-32-4208, project TCGA-GBM (Glioblastoma Multiforme). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 25.2 years (9,213 days).
Specimen TCGA-32-4208-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-GBM.553875c1-aea5-4766-801e-c3279f58cf11.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-32-4208-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/d459a4ac-d222-4b4f-9330-60feb9ca19b8

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 57; copy number 1: 10,864; copy number 2: 47,481; copy number 3: 75; copy number 4: 121; copy number 5: 176; copy number 6: 93; copy number 7: 556; copy number 8: 218; copy number 9: 110; copy number 14: 67.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-32-4208-01A-01D-1224-01): tumor purity 0.91, ploidy 1.95, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 57 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:150,584–2,926,689, 57 genes: AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1, AF067845.5, AF067845.4, DLGAP2-AS1, AC100810.6, AC100810.2, CLN8, AC100810.3, AC100810.1, AC019257.8, MIR3674, AC100810.7, MIR596, ARHGEF10, AC019257.9, AC019257.1, KBTBD11-OT1, KBTBD11, AC019257.2, AC245164.1, MYOM2, MIR7160, AC245164.2, AC245519.1, AC245519.2, AC245187.2, AC245187.1, AC245123.1, AC246817.2, AC246817.1, AC115485.1, AC023296.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,220 genes in 16 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr12:752,579–911,452, 1 gene, copy number 5 (within-gene range 1–5): WNK1.
- chr12:865,288–1,504,424, 8 genes, copy number 5: AC004765.1, RAD52, AC004803.1, ERC1, HTR1DP1, AC004672.1, AC004672.2, LINC00942.
- chr12:3,791,047–7,071,032, 121 genes, copy number 6–7 (within-gene range 1–7) (broad region; genes not listed).
- chr12:14,169,746–15,348,675, 30 genes, copy number 6–7: AC092470.1, AC135001.1, AC092112.1, MRPS18CP4, RNU6-491P, GNAI2P1, RPL30P11, ATF7IP, PLBD1, AC008114.1, RN7SKP134, PLBD1-AS1, GUCY2C, AC010168.1, AC010168.2, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP, ERP27, ARHGDIB, PDE6H, LINC01489, RERG, RERG-IT1, RERG-AS1, METTL8P1.
- chr12:15,439,527–15,440,401, 1 gene, copy number 6: AC092183.1.
- chr12:16,548,372–19,376,400, 31 genes, copy number 5–7 (within-gene range 4–7): LMO3, AC007552.2, AC007529.2, AC007529.1, SKP1P2, EEF1A1P16, AC092793.1, RNU6-837P, AC092110.1, RPL7P40, PSMC1P8, TIMM17BP1, AC048352.1, LINC02378, MIR3974, Y_RNA, RERGL, PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P.
- chr12:23,529,504–24,562,544, 1 gene, copy number 8 (within-gene range 4–8): SOX5.
- chr12:24,212,421–34,249,958, 216 genes, copy number 5–8 (broad region; genes not listed).
- chr12:44,498,616–45,445,438, 15 genes, copy number 9: AC025253.1, AC025253.2, NELL2, Y_RNA, DBX2, AC008127.1, RACGAP1P1, SSBL3P, RNA5SP361, AC009248.3, PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1.
- chr12:55,997,180–63,668,939, 194 genes, copy number 5–14 (broad region; genes not listed).
- chr12:63,651,627–63,651,930, 1 gene, copy number 6: AC027667.1.
- chr12:64,222,337–74,728,851, 197 genes, copy number 6–9 (within-gene range 1–9) (broad region; genes not listed).
- chr12:78,448,995–80,380,879, 23 genes, copy number 8 (within-gene range 1–8): AC079362.1, AC068993.1, AC068993.2, SYT1, AC090709.1, AC027288.3, MIR1252, AC027288.2, AC027288.1, NOP56P3, PAWR, AC073569.2, PPP1R12A, AC073569.3, AC073569.1, RNA5SP363, PPP1R12A-AS1, SNRPGP20, RPL7P38, RNU7-106P, OTOGL, AC078817.1, RN7SKP261.
- chr12:113,098,819–118,833,536, 110 genes, copy number 5–8 (broad region; genes not listed).
- chr12:119,989,869–120,094,494, 1 gene, copy number 7 (within-gene range 4–7): BICDL1.
- chr12:120,057,035–128,118,656, 270 genes, copy number 7 (within-gene range 2–7) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 8,484. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
